Surgical pathology report (de-identified scan), TCGA case TCGA-SH-A7BD, project TCGA-MESO (Mesothelioma), tissue source site Papworth Hospital, specimen TCGA-SH-A7BD-01A (Primary Tumor).

Sex: M

Date Collected:

Date Received:

Date Printed:

Copy To:

SPECIMEN DETAILS

Right pleural biopsies

CLINICAL INFORMATION

, cough.
Pleural fluid ? meso
Never smoker

RADIOLOGICAL / CT FINDINGS AND STAGE

Large right malignant pleural effusions

MACROSCOPIC DESCRIPTION

Multiple pieces of slightly papillary appearing pink tissue in total 2 x 1.5 cm.

N in 1 as A no reserve.

MICROSCOPIC REPORT

Multiple pleural fragments infiltrated by an epithelioid tumour. The cells express CK5/6, WT-1 and calretinin but not CK7, CEA or TTF-1 in keeping with an epithelioid malignant mesothelioma.

Reporting Pathologist:
Authorising Pathologist:

Source: NCI Genomic Data Commons file 2506e3ad-cccf-47de-a5d1-d2bc427f2fc7 (TCGA-SH-A7BD.45C80404-E67C-4FFF-9655-353F55D74312.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).